TCGA case TCGA-BP-4975 — Kidney Renal Clear Cell Carcinoma (TCGA-KIRC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney; Tissue source site: MSKCC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d97ac1d1-fc06-4e9b-b3ad-415582ff66f1

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 40 years; Vital status: Alive.

Diagnoses (1)
1. Clear cell adenocarcinoma, NOS: ICD-O-3 morphology code: 8310/3; ICD-10 code: C64.9; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 40.3 years (14,710 days); Year of diagnosis: 2006; AJCC pathologic T: T1b; AJCC pathologic N: NX; AJCC pathologic M: M0; AJCC pathologic stage: Stage I; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 1,433 days (3.9 years).
   Pathology details: Consistent pathology review: Yes.

Follow-up (1 entry)
- Days to follow up: 1,433 days (3.9 years); Disease response: Tumor Free.

Molecular and laboratory tests
- Calcium: Low.
- Platelets: Normal.
- Hemoglobin: Normal.
- Leukocytes: Elevated.

Exposures
- Exposure type: Tobacco.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-BP-4975-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.6; Intermediate dimension: 1; Shortest dimension: 0.2.
  Slide TCGA-BP-4975-01A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 10; Percent necrosis: 0; Percent stromal cells: 10.
  Slide TCGA-BP-4975-01A-01-BS1: Section location: Bottom; Percent tumor cells: 85; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 15.
- Sample TCGA-BP-4975-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-BP-4975-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 2; Intermediate dimension: 1; Shortest dimension: 0.2.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Kidney Clear Cell Renal Carcinoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; Serum calcium level: Low; Lymph nodes examined: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,433 days; disease-specific survival: no event (censored), 1,433 days; progression-free interval: no event (censored), 1,433 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-BP-4975-01A-01D-1331-01): tumor purity 0.73, ploidy 1.96, whole-genome doublings 0.
